Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A10R, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A10R-01A (Primary Tumor).

[page 1 of 2]
100-0-3

carcinoma, hepatocellular, nois 8170/3

Site: liver C22.0

hw
7/5/11

SURGICAL PATHOLOGY

Case Number :

Collection Date :

CLINICAL INFORMATION

The patient is with a liver biopsy performed at an outside hospital which showed **hepatocellular carcinoma**. The patient now undergoes right hepatic lobectomy.

GROSS DESCRIPTIONS

One appropriately labeled, formalin-filled, container is received. It contains a portion of right lobe of liver weighing 321.2 grams and measuring 6.5 x 13.2 x 6.2 cm. A small portion of tissue at the medial side was sent for tissue procurement. The surgical margin is black. There is a 7.2 cm. (lateral to medial), 3.6 cm. (anterior to posterior), and a 5.2 cm. (superior to inferior) firm, well demarcated mass at the lateral side of the specimen. The mass is tan/white with focal bile staining. Grossly, the mass approaches the capsule on the anterior, posterior, and inferior surfaces, however the capsule appears intact. The mass is 1.5 cm. away from the surgical margin. There is also a 0.7 cm. well demarcated small nodule adjacent at the medial site which is separate from the main mass. The remaining liver parenchyma is unremarkable. The attached gallbladder has been previously opened. The gallbladder appears unremarkable. No stones are identified.

BLOCK SUMMARY

- 1 - lesion with lateral capsule
- 2 - lesion
- 3 - lesion adjacent to the gallbladder
- 4 - lesion adjacent to the gallbladder
- 5 - lesion
- 6 - lesion
- 7 - surgical margin, adjacent to the gallbladder
- 8-10 - additional section with surgical margin
- 11 - smaller nodular lesion
- 12 - normal appearing liver
- 13 - surgical margin of cystic duct
- 14 - representative section of gallbladder and additional cystic duct section

hw 7/5/11

LIGHT MICROSCOPY

Light microscopic examination is performed.

Sections reveal that both of the grossly identified masses are moderately differentiated **hepatocellular carcinoma**. The tumor cells have a cord-like distribution and display moderate nuclear atypia. The tumor closely approaches the hepatic capsule, but does not invade through it. Apparent lymphovascular space invasion is present within the liver in the area of the gallbladder bed. The surrounding, non-neoplastic liver shows some bile stasis, which is predominantly intrahepatocellular. There is mild bile duct proliferation and scattered neutrophilic aggregates within portal areas and sinusoids. These findings are suggestive of a biliary obstruction, possibly secondary to the tumor. Also present are mild portal lymphocytic infiltrates, consistent with a mild (Grade 1) chronic hepatitis. Viral cytopathic effect is not noted. An iron stain shows no evidence of iron accumulation within the liver. There is no evidence of fibrosis or cirrhosis. Small foci of macrovesicular steatosis are noted.

[page 2 of 2]
DIAGNOSIS

LIVER, RIGHT LOBE, LOBECTOMY - MODERATELY DIFFERENTIATED HEPATOCELLULAR
CARCINOMA, TWO FOCI (7.2 AND 0.7 CM. GREATEST DIMENSIONS)

- LYMPHOVASCULAR SPACE INVASION IDENTIFIED

- SURGICAL MARGIN FREE OF TUMOR

GALLBLADDER, TOTAL REMOVAL - NO SPECIFIC PATHOLOGIC ABNORMALITY

Source: NCI Genomic Data Commons file e95b3959-3bc4-41b1-be00-370a51efb122 (TCGA-BC-A10R.65BE2C95-CADA-44FC-9313-14529AFF773E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).